Somatic mutation profile of tumor specimen TCGA-BR-8366-01A (aliquot TCGA-BR-8366-01A-11D-2340-08) from TCGA case TCGA-BR-8366, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 80.5 years (29,394 days).
Specimen TCGA-BR-8366-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61540000-a4e5-4478-ae9e-cc5af1893bd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8366-10A (Blood Derived Normal), aliquot TCGA-BR-8366-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2aef4f8a-c8ef-491d-8fb4-385730517b78

The open-access MAF lists 185 somatic variants for this specimen: 150 protein-altering or splice-affecting, 31 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 31, Nonsense Mutation 6, Intron 3, Splice Region 3, Frame Shift Ins 1, 3'Flank 1, Splice Site 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1922A>C p.K641T (on ENST00000288602 / NM_001374244.1; = p.K601T on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs397507484, CM123147, CM140993, COSV56070869, COSV56115928; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 29/63 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 8/66 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- RHOA | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 16/85 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1057519952, COSV69041759; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1570T>A p.W524R | Missense Mutation (SNP) | VAF 9/76 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100747680, COSV100748172, COSV61692677; called by muse, mutect2, varscan2
- ABCC12 | c.808T>C p.Y270H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60913257; called by muse, mutect2
- ABCG1 | c.1747T>G p.F583V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59203087; called by mutect2, varscan2
- AIFM1 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 55/432 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54854091; called by muse, mutect2, varscan2
- AMY2B | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 44/291 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs150795802; called by muse, mutect2, varscan2
- ANKRD28 | c.430T>A p.L144I | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV67517723; called by muse, mutect2, varscan2
- ANKRD30A | c.1949A>G p.K650R (on ENST00000611781; = p.K594R on NM_052997.2) | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.066); catalogued as COSV64608545; called by muse, mutect2, varscan2
- APLP1 | c.1679C>A p.P560H (on ENST00000221891 / NM_001024807.3; = p.P559H on NM_005166.4) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV55702815; called by muse, mutect2, varscan2
- ARNT2 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs202043975; called by muse, mutect2, varscan2
- ARNT2 | c.1462T>C p.S488P | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV57584006; called by muse, mutect2, varscan2
- ATRNL1 | c.1166A>C p.N389T | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as COSV61802536; called by muse, mutect2, varscan2
- ATRX | c.4047C>A p.D1349E | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.988); catalogued as COSV64874986, COSV64882477; called by muse, mutect2, varscan2
- BBX | c.1131A>C p.Q377H | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV57882788; called by muse, mutect2, varscan2
- BCOR | c.4540C>T p.R1514* (on ENST00000378444 / NM_001123385.2; = p.R1480* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as CM0910704, COSV60703956, COSV60716852; called by mutect2, varscan2
- CD22 | c.1684T>A p.S562T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.479); catalogued as COSV50051531; called by muse, mutect2, varscan2
- CD5L | c.733A>G p.R245G | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs542506978, COSV63821649; called by muse, mutect2, varscan2
- CDCP1 | c.362T>G p.L121R | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56104862; called by muse, mutect2, varscan2
- CEP85L | c.1506A>C p.K502N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV63822306; called by muse, mutect2, varscan2
- CLN8 | c.550T>G p.W184G | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.265); catalogued as COSV58670246; called by muse, mutect2, varscan2
- COLEC12 | c.26A>T p.E9V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV68370054; called by muse, mutect2, varscan2
- CSRNP3 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV58776851, COSV58777533; called by muse, mutect2, varscan2
- CYLC1 | c.1036G>T p.D346Y | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV61411507, COSV61416363; called by muse, mutect2, varscan2
- DBH | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201078152, COSV67549111; called by muse, mutect2, varscan2
- DISP3 | c.2105A>T p.N702I | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as COSV53825502; called by muse, mutect2, varscan2
- EFEMP1 | c.407A>C p.N136T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as rs773783473, COSV62615784; called by muse, mutect2, varscan2
- EIF4A1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/127 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV53442969; called by muse, mutect2, varscan2
- ELAVL1 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60966275; called by muse, mutect2, varscan2
- ERGIC3 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs749724539, COSV54137044; called by muse, mutect2, varscan2
- F8 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM153193, COSV64272151; called by muse, mutect2, varscan2
- FAM171B | c.2429A>G p.K810R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV59002588; called by muse, mutect2, varscan2
- FOXM1 | c.1976T>C p.L659P | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV61205766; called by muse, mutect2, varscan2
- GABBR1 | c.2158A>G p.M720V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV63542057; called by muse, mutect2, varscan2
- GHSR | c.1066T>C p.S356P | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV53838513; called by muse, mutect2
- GLI3 | c.3397G>A p.G1133R | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs768034418, COSV67884684; called by muse, mutect2
- GLRA4 | c.511T>A p.S171T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as COSV65455169, COSV65455634; called by muse, mutect2, varscan2
- GP1BA | c.40T>G p.L14V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV56699044; called by muse, mutect2, varscan2
- GYS2 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.439); catalogued as rs750090305, COSV53922439; called by muse, mutect2, varscan2
- HCRTR2 | c.1048C>T p.H350Y | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63795195; called by muse, mutect2, varscan2
- HRH4 | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56927869; called by muse, mutect2, varscan2
- HSPA12A | c.1372A>G p.S458G | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100979841, COSV65021891; called by muse, mutect2, varscan2
- HSPA4L | c.1120A>G p.R374G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56544922; called by muse, mutect2, varscan2
- IGFALS | c.1072T>G p.F358V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51905513; called by muse, mutect2, varscan2
- IGKV2D-30 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs770422279; called by muse, mutect2, varscan2
- INPP5A | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61248417; called by muse, mutect2, varscan2
- INVS | c.1369A>T p.R457* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | catalogued as COSV52440826; called by muse, mutect2
- ITIH6 | c.743T>G p.V248G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV54488361; called by muse, mutect2, varscan2
- KCNC3 | c.1655A>C p.K552T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65387191; called by muse, mutect2, varscan2
- KCNQ1 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199472762, CM043017, COSV50105407; ClinVar: not provided; called by muse, mutect2
- KIR3DL1 | c.471A>C p.K157N | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV58489894; called by muse, mutect2, varscan2
- KRT85 | c.1516T>C p.F506L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.225); catalogued as COSV57736575; called by muse, mutect2, varscan2
- LDHB | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV63364565; called by muse, mutect2, varscan2
- LENG9 | c.1246_1247del p.Q416Vfs*58 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | catalogued as rs778740821; called by mutect2, varscan2
- LSM11 | c.620A>C p.K207T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53848025; called by muse, mutect2, varscan2
- MAMLD1 | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs913468414, COSV53373935; called by muse, mutect2, varscan2
- MED14 | c.4290A>C p.Q1430H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV61356636; called by muse, mutect2
- MERTK | c.2813G>A p.W938* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | catalogued as COSV54927703; called by muse, mutect2, varscan2
- MLLT3 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV63496975; called by muse, varscan2
- MLNR | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.643); catalogued as COSV54532344; called by muse, mutect2
- MMP17 | c.794T>C p.I265T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62178989; called by muse, mutect2, varscan2
- MTMR3 | c.3557A>G p.D1186G | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV60303555; called by muse, mutect2, varscan2
- MYH11 | c.4248T>G p.D1416E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.107); catalogued as COSV55550220; called by muse, mutect2, varscan2
- MYH8 | c.238T>G p.F80V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV67963438; called by muse, mutect2, varscan2
- MYO1E | c.330C>A p.I110= | Splice Region (SNP) | VAF 7/45 reads (16%) | catalogued as COSV55685673; called by muse, mutect2, varscan2
- NAPRT | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV52784148; called by muse, mutect2
- NDST4 | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.158); catalogued as COSV52116295; called by muse, mutect2
- NEFH | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.741); catalogued as COSV60216476; called by muse, mutect2, varscan2
- NFATC3 | c.2402C>T p.S801F | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV60473069; called by muse, mutect2
- NIBAN3 | c.1871T>C p.F624S | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.986); catalogued as COSV53108497; called by muse, mutect2
- NLRP3 | c.1850A>C p.K617T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV60222863; called by muse, mutect2, varscan2
- NSG1 | c.113T>C p.F38S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV67574914; called by mutect2, varscan2
- NUP93 | c.785T>G p.L262R | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57430229; called by muse, mutect2, varscan2
- OR1B1 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV59171528; called by muse, mutect2, varscan2
- OR52I1 | c.571T>G p.L191V | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56168228; called by muse, mutect2, varscan2
- OR5D14 | c.200A>G p.H67R | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100162672, COSV59456041; called by muse, mutect2
- PCDHB15 | c.2207T>A p.L736Q | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as COSV50893146; called by muse, mutect2, varscan2
- PCDHB5 | c.1580A>G p.E527G | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV50649791; called by muse, mutect2, varscan2
- PCDHGA2 | c.1022A>C p.N341T | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53930975; called by muse, mutect2, varscan2
- PDIA6 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs200773446, COSV99694394; called by muse, mutect2, varscan2
- PIGO | c.2285C>T p.P762L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767539954, COSV53053376; called by mutect2, varscan2
- PIK3CA | c.544T>C p.Y182H | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1055592960, COSV55912222; called by muse, mutect2, varscan2
- PLAAT4 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55373053; called by muse, mutect2, varscan2
- PNLIP | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1298412725, COSV65040205; called by muse, mutect2
- PROM2 | c.1544T>C p.L515P | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58297656; called by muse, mutect2, varscan2
- PSG11 | c.299C>A p.T100K | Missense Mutation (SNP) | VAF 38/313 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as COSV60454756; called by muse, mutect2, varscan2
- PTF1A | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 29/181 reads (16%) | catalogued as COSV64734985; called by muse, mutect2, varscan2
- RANBP2 | c.6182A>T p.K2061I | Missense Mutation (SNP) | VAF 57/440 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51699661; called by muse, mutect2, varscan2
- RGS10 | c.204T>G p.D68E (on ENST00000369101; = p.D62E on NM_002925.3) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV64861935; called by muse, mutect2, varscan2
- RP1 | c.6060T>G p.N2020K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV55114866; called by muse, mutect2, varscan2
- RPA4 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV61266302; called by muse, mutect2, varscan2
- RPE65 | c.449A>T p.N150I | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV52015210; called by muse, mutect2, varscan2
- SAGE1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV61012753; called by muse, mutect2, varscan2
- SAGE1 | c.1525C>A p.P509T | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61012766; called by muse, mutect2, varscan2
- SCAP | c.3158G>T p.S1053I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV55544062; called by muse, mutect2, varscan2
- SCN11A | c.1004C>A p.P335H | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100182291; called by muse, mutect2
- SEPTIN12 | c.293-2A>C p.X98_splice | Splice Site (SNP) | VAF 7/55 reads (13%) | catalogued as COSV51616560; called by muse, mutect2, varscan2
- SEZ6L | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753580054, COSV50661641; called by muse, mutect2
- SF3B4 | c.705A>G p.P235= | Splice Region (SNP) | VAF 8/37 reads (22%) | catalogued as COSV54965109; called by muse, mutect2, varscan2
- SHOC1 | c.3519A>C p.K1173N | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV59500055; called by muse, mutect2
- SKAP1 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); catalogued as COSV61145987; called by muse, mutect2, varscan2
- SLC16A6 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1555748429, COSV59177023; called by muse, mutect2, varscan2
- SLC46A2 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65289494, COSV65289890; called by muse, mutect2, varscan2
- SLC4A4 | c.1264G>A p.D422N (on ENST00000264485 / NM_001098484.3; = p.D378N on NM_003759.4) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV52621837; called by muse, mutect2
- SLC6A16 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV60027695; called by muse, mutect2, varscan2
- SLC9A2 | c.1767A>C p.K589N | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.14); catalogued as COSV52131066; called by muse, mutect2, varscan2
- SNRPA | c.107A>G p.Q36R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV54680891; called by muse, mutect2, varscan2
- SNX29 | c.2111A>C p.K704T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV60056892; called by muse, mutect2
- SOCS5 | c.926A>G p.E309G | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as COSV60604329; called by muse, mutect2, varscan2
- SOHLH1 | c.660A>G p.S220= | Splice Region (SNP) | VAF 4/25 reads (16%) | catalogued as rs753040915, COSV53681305; called by mutect2, varscan2
- SPOCD1 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99930373; called by muse, mutect2
- TAB3 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV55836253; called by muse, mutect2
- TBC1D28 | c.239A>C p.K80T | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100561075; called by muse, mutect2, varscan2
- TBXA2R | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64343497; called by muse, varscan2
- TLE2 | c.1766C>T p.T589M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53579323; called by muse, mutect2
- TMCC3 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770261214, COSV54153032; called by muse, mutect2
- TMEM178A | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV56141597; called by muse, mutect2, varscan2
- TNC | c.3193G>A p.A1065T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.041); catalogued as rs757368961, COSV60783689; called by muse, mutect2
- TTLL2 | c.1562T>C p.L521P | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV53443448; called by muse, mutect2, varscan2
- TTN | c.76378G>A p.G25460S (on ENST00000591111; = p.G18036S on NM_003319.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | PolyPhen probably damaging (0.999); catalogued as rs1441990001, COSV59995498; called by muse, mutect2, varscan2
- TUBB2B | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV52533488; called by muse, mutect2, varscan2
- TYROBP | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs150310136; called by muse, mutect2, varscan2
- USP9X | c.2509A>G p.K837E | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV61065513; called by muse, mutect2, varscan2
- VPS29 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV62194730; called by muse, mutect2, varscan2
- VWF | c.7685A>C p.Q2562P | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV54617384; called by muse, mutect2
- WRN | c.1145A>C p.K382T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53298995, COSV99988474; called by mutect2, varscan2
- WWC2 | c.3429G>C p.E1143D | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.805); catalogued as rs1426073679, COSV67857288; called by muse, mutect2, varscan2
- XKR3 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs1342475833, COSV100509211; called by muse, mutect2
- YJU2 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV53605945; called by muse, mutect2, varscan2
- ZFPM2 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs369889214; called by muse, mutect2, varscan2
- ZKSCAN7 | c.829A>G p.K277E | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1472830490, COSV56272442; called by muse, mutect2, varscan2
- ZNF208 | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.96); catalogued as rs372427595; called by muse, mutect2
- ZNF280B | c.953A>C p.N318T | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV64528720; called by muse, mutect2, varscan2
- ZNF331 | c.325A>G p.K109E | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.133); catalogued as COSV53476201; called by muse, mutect2, varscan2
- ZNF441 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV63539602; called by muse, mutect2, varscan2
- ZNF486 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.063); catalogued as rs1555715996, COSV58718604; called by muse, varscan2
- ZNF551 | c.1166G>A p.R389K | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.699); catalogued as COSV56592257; called by muse, mutect2, varscan2
- ZNF566 | c.655A>G p.K219E | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV67573582; called by muse, mutect2, varscan2
- ZNF592 | c.2105A>G p.D702G | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55436274; called by muse, mutect2, varscan2
- ZNF598 | c.719T>G p.F240C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV70910398; called by muse, mutect2, varscan2
- ZNF676 | c.1667A>C p.K556T (on ENST00000650058; = p.K524T on NM_001001411.3) | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as COSV68092828; called by muse, mutect2, varscan2
- ZSCAN21 | c.563A>C p.E188A | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV52850177; called by muse, mutect2, varscan2
- ABCC4 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- BRWD3 | c.1748T>G p.L583R | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- OGFRL1 | c.967A>C p.S323R | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.416); called by muse, mutect2
- TRIM11 | c.1374A>C p.K458N | Missense Mutation (SNP) | VAF 2/19 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.674); called by muse, mutect2
- VN1R5 | c.511T>C p.S171P | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ZC3H12A | c.1676dup p.L560Afs*40 | Frame Shift Ins (INS) | VAF 7/69 reads (10%) | called by mutect2, varscan2
- CENPE | c.7926T>G p.S2642= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV54379807; called by muse, mutect2, varscan2
- CFAP94 | c.1716C>T p.I572= (on ENST00000320267 / NM_001352064.2; = p.I578= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100209680, COSV57231620; called by muse, mutect2, varscan2
- COL14A1 | c.109A>C p.R37= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV52852290; called by muse, mutect2
- CSMD3 | c.5688C>T p.V1896= (on ENST00000297405 / NM_001363185.1; = p.V1792= on NM_052900.3) | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs768980020, COSV52143364, COSV52243265; called by muse, mutect2, varscan2
- DNAH2 | c.3804T>C p.F1268= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV101209552; called by muse, mutect2, varscan2
- ERCC6L2 | c.3852T>G p.S1284= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- FCRL2 | c.738C>A p.T246= | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as rs764743327, COSV63833289; called by muse, mutect2, varscan2
- FTSJ3 | c.2266A>C p.R756= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV63789851; called by muse, mutect2, varscan2
- GABRA3 | c.477A>G p.S159= | Silent (SNP) | VAF 27/166 reads (16%) | catalogued as COSV64797682; called by muse, mutect2, varscan2
- GALNT7 | c.231A>G p.G77= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV53928886; called by muse, mutect2, varscan2
- GPR158 | c.2679C>T p.H893= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV66268642; called by muse, mutect2, varscan2
- ITGB7 | c.1578G>A p.G526= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV57238459; called by muse, mutect2
- NEO1 | c.3537A>G p.P1179= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV56070107; called by muse, mutect2, varscan2
- NFASC | c.1602A>G p.R534= (on ENST00000339876 / NM_001378329.1; = p.R545= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV58363759; called by muse, mutect2, varscan2
- OR11H12 | c.456T>A p.T152= | Silent (SNP) | VAF 28/415 reads (7%) | catalogued as COSV73569217; called by muse, mutect2
- OR2G2 | c.657C>T p.V219= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV60740226; called by muse, mutect2, varscan2
- OSBPL3 | c.606T>C p.S202= | Silent (SNP) | VAF 24/196 reads (12%) | catalogued as COSV57655481; called by muse, varscan2
- PDE3A | c.903C>T p.S301= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV62971313; called by muse, mutect2, varscan2
- PLXNB3 | c.4227G>A p.S1409= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs1452761898, COSV62796843; called by muse, mutect2, varscan2
- PYGL | c.1062T>C p.F354= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV53585339; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1596C>T p.A532= | Silent (SNP) | VAF 13/154 reads (8%) | catalogued as rs778467297, COSV50248798; called by muse, mutect2
- RAI14 | c.501C>A p.I167= | Silent (SNP) | VAF 33/227 reads (15%) | catalogued as COSV54292875; called by muse, mutect2, varscan2
- SLC9C2 | c.1566T>C p.F522= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV62945252; called by muse, mutect2, varscan2
- SMAD4 | c.1569C>T p.C523= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV100747628, COSV100748170, COSV61684051; called by muse, mutect2, varscan2
- STAG3 | c.3309G>A p.P1103= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs147288707; called by muse, mutect2, varscan2
- TGFB2 | c.174T>G p.P58= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs775518697, COSV65108912; called by muse, mutect2, varscan2
- TUBA3D | c.1341C>T p.G447= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as rs368534303; called by muse, varscan2
- ZFP1 | c.876A>G p.G292= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV60033006; called by muse, mutect2, varscan2
- ZMAT1 | c.1647A>G p.K549= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV65658259; called by muse, mutect2, varscan2
- ZNF470 | c.330T>C p.D110= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV100401367; called by muse, mutect2
- ZNF831 | c.5001C>T p.S1667= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs745373686, COSV64039251; called by muse, mutect2, varscan2
- CA6 | c.259+2156C>T | Intron (SNP) | VAF 3/23 reads (13%) | catalogued as rs1445752073, COSV101077656; called by muse, mutect2
- FABP5P3 | chr7:152445752 A>C | 3'Flank (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- FOXP2 | c.258+36169A>T | Intron (SNP) | VAF 11/107 reads (10%) | catalogued as COSV100647274; called by muse, mutect2, varscan2
- TCAF2 | c.2505+29G>A | Intron (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100633720; called by muse, mutect2, varscan2
